Surgical pathology report (de-identified scan), TCGA case TCGA-WK-A8XO, project TCGA-SARC (Sarcoma), tissue source site Brigham and Women's Hospital, specimen TCGA-WK-A8XO-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Report Status: Final

Type: Surgical Pathology
Specimen Type: Peritoneum
Procedure Date:
Ordering Provider:

ICD-0-3

Liposarcoma, dedifferentiated
885813

Site: Retroperitoneum
C48.0

J) 5/5/14

Resident:
Pathologist:

PATHOLOGIC DIAGNOSIS:

- A. LEFT PELVIC SIDE WALL DEPOSIT:
Fibrovascular tissue with chronic inflammation and foreign body giant cell reaction, negative for tumor.
- B. RIGHT RETROPERITONEAL MASS:
DEDIFFERENTIATED LIPOSARCOMA, 5 cm.
Mitoses number 40:10 HPF.
No necrosis identified.
- C. OMENTAL NODULE:
DEDIFFERENTIATED LIPOSARCOMA involving fibroadipose tissue.
- D. ILEUM AND RIGHT COLON:
DEDIFFERENTIATED LIPOSARCOMA, 1.9 cm, involving the wall of the small intestine, invading into the submucosa.
Colonic and ileal resection margins are negative for tumor.
Four lymph nodes, negative for tumor (0:4).
- E. SMALL BOWEL MESENTERY LYMPH NODES:
Three lymph nodes, negative for tumor (0:3).

CLINICAL DATA:

History: Dedif LPS
Operation: Resection of duodenal liposarcoma, sm bowel resection
Operative Findings: Not provided
Clinical Diagnosis: Duodenal liposarcoma

TISSUE SUBMITTED:

- A. LT pelvic side wall deposit
- B. RT retroperitoneal mass - short sup - long lat - tissue bank
- C. Omental nodule
- D. Ileum + RT colon
- E. Sm bowel mesentery lymph node

GROSS DESCRIPTION:

The specimen is received fresh, in five parts, labeled with the patient's name and unit number.

Part A, "#1. Left pelvic sidewall deposits", consists of soft tissue fragments of 2.5 x 1.0 x 1.0 cm.

Micro A1: Soft tissue fragments, 1 frag,

Part B, "#2. Right retroperitoneal mass stitch superior, long posterior tissue bank", consists of a 35.5-g tan/yellow lobulated multifocally disrupted oriented soft tissue mass (5 x 5 x 4.5 cm) with a short stitch superior and long stitch lateral. The excision appears marginal grossly. The specimen is inked per protocol. There is on the lateral aspect of the specimen additional fatty piece attached measuring 2.7 x 2.1 x 0.6 cm. There is a tan/white lobulated firm cut surface of the tumor. Representative section of the tumor

[page 2 of 2]
Pathology Report

is submitted for cytogenetics and tissue bank and for
Photograph is taken.

lab.

Micro B1: Medial inferior lateral margin, 1 frag,
Micro B2: Anterior medial margin, 1 frag,
Micro B3: Posterior inferior margin, 1 frag,
Micro B4: Lateral margin, 2 frag,
Micro B5: Medial superior margin, 1 frag,
Micro B6: Anterior inferior margin, 1 frag,
Micro B7: Superior resection margin, 1 frag,
Micro B8-B10: Additional tumor sampling, 3 frags,

Part C, "#3. Omental nodule", consists of a white firm nodule of 1.2 cm in diameter.

Micro C1-C2: Nodule bisected, 2 frags,

Part D, "#4. Ileum and right colon frozen section", consists of a segment of ileum measuring 34.0 cm in length x 3.0 cm in diameter with a right colon of 12.0 cm in length x 8.0 cm in diameter with a radial resection margin of 6.0 cm. The mucosa of the bowel is unremarkable. There is mesenteric nodule in the terminal ileum measuring 1.6 cm in diameter pushing the submucosa located at 20.0 cm from the ileal resection margin and 11.0 cm from the ICV.

Micro D1: Ileal resection margin, 1 frag,
Micro D2: Colon resection margin, 1 frag,
Micro D3: Radial resection margin, 2 frags,
Micro D4: Lymph node?, 1 frag,
Micro D5: Lymph node, 1 frag,
Micro D6: Lymph node, 2 frags,
Micro D7-D8: Ileal mesenteric mass, 1 frag,
Micro D9-D10: Colonic mucosa, 4 frags.
Micro D11-D14: Ileal mucosa, 8 frags,

Part E, "#5. Small bowel mesentery lymph node", consists of a lymph node of 1.3 x 0.5 x 0.5 cm with fibroadipose tissue measuring 2.0 x 1.0 x 1.0 cm in aggregate.

Micro E1: Lymph node and fibroadipose tissue, 3 frags,

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by

Electronically signed on

Source: NCI Genomic Data Commons file 0f7975b5-bf33-4bfb-ab13-8574bddf91a3 (TCGA-WK-A8XO.1AE1A944-8D73-405E-9670-5ADC3F8906E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).